Somatic mutation profile of tumor specimen TCGA-AR-A0U3-01A (aliquot TCGA-AR-A0U3-01A-11D-A10G-09) from TCGA case TCGA-AR-A0U3, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 59.6 years (21,755 days).
Specimen TCGA-AR-A0U3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fdda3fed-ddc3-4ce1-a697-168d6bdf1e64.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A0U3-10A (Blood Derived Normal), aliquot TCGA-AR-A0U3-10A-01D-A10G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36bb27db-14c7-403b-9a19-3df4f98b3b24

The open-access MAF lists 38 somatic variants for this specimen: 28 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 8, Nonsense Mutation 4, Frame Shift Del 3, Frame Shift Ins 1, Splice Site 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.501del p.Q167Hfs*3 | Frame Shift Del (DEL) | VAF 27/44 reads (61%) | catalogued as rs1567553148, COSV52701014, COSV53108662, COSV53327706, COSV53408532; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCC2 | c.3436C>T p.R1146C | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs377550597; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADCY9 | c.2099G>T p.G700V | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.24); catalogued as COSV53582688; called by muse, mutect2, varscan2
- ALKBH7 | c.429G>A p.M143I | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs773836675, COSV55533075; called by muse, mutect2, varscan2
- BCL9 | c.3400C>T p.R1134W | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs782131021, COSV52351357; called by muse, mutect2, varscan2
- CTR9 | c.2110-2A>G p.X704_splice | Splice Site (SNP) | VAF 15/231 reads (6%) | catalogued as COSV100797549; called by muse, mutect2
- DAO | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as rs760006596, COSV57324867; called by muse, mutect2, varscan2
- DNAH5 | c.11241G>A p.M3747I | Missense Mutation (SNP) | VAF 86/271 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV54231450; called by muse, mutect2, varscan2
- HDAC5 | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated, low confidence (0.32); PolyPhen probably damaging (0.994); catalogued as COSV99871176; called by muse, mutect2, varscan2
- HPD | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as rs752018560, COSV100000256; called by muse, mutect2
- KIF2C | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 51/88 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs760237957, COSV64765831; called by muse, mutect2, varscan2
- KLF17 | c.445G>A p.G149R | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.077); catalogued as COSV64857238; called by muse, mutect2, varscan2
- MAPKBP1 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as rs759447759, COSV52967108; called by muse, mutect2, varscan2
- MEIOC | c.2157C>G p.Y719* | Nonsense Mutation (SNP) | VAF 82/133 reads (62%) | catalogued as COSV63441748; called by muse, mutect2, varscan2
- NECTIN3 | c.787T>G p.L263V | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV60553884; called by muse, mutect2, varscan2
- NMT1 | c.1486C>T p.Q496* | Nonsense Mutation (SNP) | VAF 47/78 reads (60%) | catalogued as COSV51963194; called by muse, mutect2, varscan2
- NPAP1 | c.2632del p.Q878Rfs*14 | Frame Shift Del (DEL) | VAF 41/138 reads (30%) | catalogued as COSV61512308; called by mutect2, pindel, varscan2
- PCDHGB6 | c.582A>T p.L194F | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54051005; called by muse, mutect2, varscan2
- PKD1L2 | c.705_707delinsG p.N236Pfs*26 | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | catalogued as rs55980345; called by pindel, varscan2*
- RFXANK | c.40C>T p.Q14* | Nonsense Mutation (SNP) | VAF 29/92 reads (32%) | catalogued as COSV50773528; called by muse, mutect2, varscan2
- RGS5 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58353164; called by muse, mutect2, varscan2
- SLX4 | c.3445G>T p.D1149Y | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as COSV53569482; called by muse, mutect2, varscan2
- TMEM9B | c.563A>T p.K188M | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58428340; called by muse, mutect2, varscan2
- UNC45A | c.2325G>T p.K775N | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.164); catalogued as COSV67793973; called by muse, mutect2, varscan2
- VPS53 | c.1309G>T p.D437Y (on ENST00000571805 / NM_001366253.2; = p.D408Y on NM_018289.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/105 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52139608; called by muse, mutect2, varscan2
- WASF3 | c.1504G>A p.D502N | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs538866473, COSV58966978; called by muse, mutect2, varscan2
- WSB2 | c.1199C>A p.T400K | Missense Mutation (SNP) | VAF 56/187 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.495); catalogued as COSV57479054; called by muse, mutect2, varscan2
- IQUB | c.484dup p.S162Ffs*21 | Frame Shift Ins (INS) | VAF 60/177 reads (34%) | called by mutect2, pindel, varscan2
- CALML6 | c.330C>T p.S110= | Silent (SNP) | VAF 27/46 reads (59%) | catalogued as rs764129043, COSV57071241; called by muse, mutect2, varscan2
- CELA2B | c.69G>A p.A23= | Silent (SNP) | VAF 42/60 reads (70%) | catalogued as rs368888301; called by muse, mutect2, varscan2
- FEZF2 | c.1023G>T p.A341= | Silent (SNP) | VAF 45/119 reads (38%) | catalogued as COSV51864839; called by muse, mutect2, varscan2
- MGAM | c.4509G>A p.Q1503= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as COSV72076097; called by muse, varscan2
- PLD5 | c.1587C>T p.G529= (on ENST00000442594; = p.G467= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 113/415 reads (27%) | catalogued as rs763708663, COSV59172070; called by muse, mutect2, varscan2
- SMCHD1 | c.3774C>T p.L1258= | Silent (SNP) | VAF 81/213 reads (38%) | catalogued as COSV55270705; called by muse, mutect2, varscan2
- TEK | c.495G>A p.V165= | Silent (SNP) | VAF 21/33 reads (64%) | catalogued as rs745866045, COSV66236051; called by muse, mutect2, varscan2
- UHRF1BP1L | c.987A>G p.L329= | Silent (SNP) | VAF 74/163 reads (45%) | catalogued as COSV54443593; called by muse, mutect2, varscan2
- RFX4 | c.378-2009C>T | Intron (SNP) | VAF 29/87 reads (33%) | catalogued as rs773337962, COSV57575362; called by muse, mutect2, varscan2
- SLC7A1 | c.*2G>A | 3'UTR (SNP) | VAF 5/18 reads (28%) | catalogued as rs1304883376, COSV101060323; called by muse, mutect2
